Somatic mutation profile of tumor specimen TCGA-J8-A3YE-01A (aliquot TCGA-J8-A3YE-01A-12D-A23M-08) from TCGA case TCGA-J8-A3YE, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 31.3 years (11,446 days).
Specimen TCGA-J8-A3YE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 61c194cc-8594-4922-93c2-3a3de978bb82.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J8-A3YE-10A (Blood Derived Normal), aliquot TCGA-J8-A3YE-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8256e6a5-7521-4e4c-9610-bbaf2f900a6f

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ATM | c.6683C>T p.T2228I | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV53727786; called by muse, mutect2, varscan2
- CASZ1 | c.1677C>A p.N559K | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV59732428; called by muse, mutect2
- EFR3A | c.1994T>C p.I665T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1236570912, COSV54453452, COSV54457373; called by muse, mutect2, varscan2
- KDM2A | c.620G>A p.C207Y | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101284594; called by muse, mutect2
- SPTA1 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 119/295 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.385); catalogued as COSV63749322; called by muse, mutect2, varscan2
- ADSS1 | c.1081del p.L361* | Frame Shift Del (DEL) | VAF 24/71 reads (34%) | called by mutect2, pindel, varscan2
- RIC1 | c.705T>C p.S235= | Silent (SNP) | VAF 77/186 reads (41%) | catalogued as COSV52605299; called by muse, mutect2, varscan2
